Gene-level copy-number profile of tumor specimen ALCH-B3C3-TTP1-A from ALCHEMIST case ALCH-B3C3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.1 years (26,717 days).
Specimen ALCH-B3C3-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ca9b0e35-3946-41ae-bc12-3ea11f722b09.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3C3-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/f4c2d433-3dfc-4180-84c1-99e1adb829ed

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 16,316; copy number 2: 38,937; copy number 3: 2,093; copy number 4: 72; copy number 5: 895; copy number 6: 69; copy number 14: 1; copy number 16: 1; copy number 18: 1; copy number 36: 1.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:22,024,125–22,048,809, 2 genes: NPM2, FGF17.
- chr9:114,615,455–114,615,568, 1 gene (within-gene range 0–2): Y_RNA.
- chr10:100,996,618–101,007,836, 1 gene (within-gene range 0–2): LZTS2.
- chr17:39,603,536–39,609,777, 1 gene: NEUROD2.
- chr19:13,862,063–13,880,757, 3 genes: NANOS3, MIR181C, MIR181D.
- chr19:43,211,791–43,269,530, 2 genes: CEACAMP10, PSG9.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 968 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–58,915, 1 gene, copy number 5: AC113430.1.
- chr8:78,805,293–144,118,328, 963 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr11:1,947,278–1,993,670, 3 genes, copy number 14–36: MRPL23, MRPL23-AS1, LINC01219.
- chr21:43,461,960–43,479,534, 1 gene, copy number 16 (within-gene range 4–16): LINC00313.

Autosomal genes at a single copy (total copy number 1): 16,170. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
